Surgical pathology report (de-identified scan), TCGA case TCGA-94-7557, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-7557-01A (Primary Tumor).

[page 1 of 5]
Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Encounter info:

* Final Report *

(Verified)

Patient Name:

MRN:

DOB:

Location:

Client:

Submitting

Phys:

Gender:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LUNG, LEFT UPPER LOBE, WEDGE EXCISION, A1FS:
- ADENOCARCINOMA, MIXED SUBTYPE, PREDOMINANTLY A LEPIDIC PATTERN OF GROWTH WITH LESSER AREAS OF MICROPAPILLARY PATTERN OF GROWTH, MODERATELY DIFFERENTIATED (SEE PARTB).
- NO VISCERAL PLEURAL INVASION IS IDENTIFIED.
- LYMPHOVASCULAR INVASION IS PRESENT.
- SEE PART B FOR FINAL MARGIN.
- SEE SYNOTIC REPORT.
- B. LUNG, LEFT UPPER LOBE, LOBECTOMY, B1FS:
- INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, 4.5 X 3.5 X 1.9 CM.
- NO VISCERAL PLEURAL INVASION IS IDENTIFIED.
- RESIDUAL ADENOCARCINOMA, 4.0 CM IN GREATEST DIMENSION.
- BRONCHOVASCULAR MARGINS ARE NEGATIVE FOR CARCINOMA..
- UNINVOLVED LUNG PARENCHYMA WITH EMPHYSEMATOUS CHANGES.
- FOUR BENIGN PERIBRONCHIAL LYMPH NODES (0/4).
- ONE BENIGN INTRAPARENCHYMAL LYMPH NODE (0/1).

Printed by:
Printed on:

Page 1 of 5
(Continued)

[page 2 of 5]
Path Reports

* Final Report *

- SEE SYNOPTIC REPORT.

C. MEDIASTINUM, LEVEL 6, LYMPH NODE BIOPSY:
- SIX BENIGN LYMPH NODE FRAGMENTS (0/6).

D. MEDIASTINUM, LEVEL 7, LYMPH NODE BIOPSY:
- ADENOCARCINOMA SIMILAR TO ABOVE INVOLVING LUNG PARENCHYMA.
- NO LYMPH NODE TISSUE IS IDENTIFIED (ENTIRELY SUBMITTED SPECIMEN).

Synoptic Worksheet

B. Left upper lobe lung, FS:

Specimen:	Lobe(s) of lung: left upper lobe
Procedure:	Lobectomy
Specimen Integrity:	Intact
Specimen Laterality:	Left
Tumor Site:	Upper lobe
Tumor Focality:	Separate tumor nodules in same lobe
Histologic Type:	Other: Two foci of carcinoma, squamous cell carcinoma and separate adenocarcinoma
Histologic Grade:	Other: Squamous cell carcinoma: poorly differentiated, Adenocarcinoma: Moderately differentiated
Tumor Size:	Cannot be determined: Squamous cell carcinoma: 4.5 cm; Adenocarcinoma: 4 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not identified
Bronchial Margin:	Uninvolved by invasive carcinoma Squamous cell carcinoma in situ (CIS) not identified at bronchial margin
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 23 mm Margin closest to invasive carcinoma:: bronchial, vascular
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present

Printed by:
Printed on:

Page 2 of 5
(Continued)

[page 3 of 5]
Anat Path Reports

* Final Report *

TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Nodes examined: 11 Nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Emphysema

Clinical History

Left VATS, lobectomy. Left lung mass.

Specimen(s) Received

A: Left upper lobe wedge

B: Left upper lobe lung

C: #6 lymph node

D: #7 lymph node

Gross Description

Specimen A is received fresh, labeled with the patient's name, medical record number and is designated as "left upper lobe wedge." The specimen consists of a wedge of lung measuring 7.0 x 3.4 x 2.3 cm. The specimen is incised prior to receipt. There is a nodule measuring approximately 1.5 cm in greatest dimension present in the specimen, causing pleural puckering, less than 0.5 cm from the nearest staple line. Representative section of the tissue is submitted for frozen section (A1FS). Representative section of the remainder of the specimen is submitted as follows.

Specimen B is received fresh for intraoperative consultation labeled with the patient's name, medical record number, and is designated as "left upper lobe lung." The specimen consists of a lobe of lung weighing 180 grams and measuring 11.0 x 8.0 x 5.0 cm. There is a mass measuring 4.5 x 3.5 x 1.9 cm abutting the visceral pleura, causing puckering. The mass is 1.0 cm from the staple line of the presumed previous wedge resection. The mass is 2.3 cm from the bronchial and vascular margins. The mass surrounds the large vessel (probable vein) but does not appear to invade it. No gross bronchovascular invasion is identified. An additional area of pleural thickening spanning approximately 4.0 cm is present, grossly 1.0 cm from the aforementioned mass and 1.0 cm from the bronchovascular margins. The thickening abuts the staple line. Multiple possible peribronchial lymph nodes are identified. The bronchial margin is submitted for frozen section (B1FS). No other lesions are identified. The area of visceral pleura puckering overlying the 4.5 cm mass is inked blue. Representative sections are submitted as follows.

Specimen C is received in formalin, labeled with the patient's name, medical record number, and is designated as "#6 lymph

Printed by:
Printed on:

Page 3 of 5
(Continued)

[page 4 of 5]
Anat Path Reports

* Final Report *

node." The specimen consists of two soft tissue fragments, in aggregate measuring 2.9 x 2.2 x 1.0 cm. The specimen is entirely submitted as follows. [REDACTED]

Specimen D is received in formalin, labeled with the patient's name, medical record number, and is designated as "#7 lymph node." The specimen consists of a soft tissue fragment measuring 1.0 cm in greatest dimension. The specimen is bisected and entirely submitted in one cassette. [REDACTED]

A2,3: Remainder of mass and visceral pleura (blue)
A4: Representative uninvolved lung
B2: Vascular margin
B3,4: Tumor, vasculature, bronchi, visceral pleura puckering
B5: Tumor, normal
B6: Tumor, bronchus, lymph node
B7: Multiple possible peribronchial lymph nodes, whole
B8: Remainder of lymph node from section B6, fragmented
B9: One possible peribronchial lymph node, fragmented
B10: One possible peribronchial lymph node, fragmented
B11: Possible intraparenchymal lymph nodes, whole
B12: Visceral pleural thickening near staple line
B13: Hilar unremarkable lung
B14: Peripheral unremarkable lung
B15,16: Additional sections of pleural thickening
B17,18: Tissue in between mass and pleural thickening
C1: Smallest soft tissue fragment, whole
C2,3: Largest soft tissue fragment, bisected

[REDACTED]

Intraoperative Consult Diagnosis

A1FS: LUNG, LEFT UPPER LOBE (FROZEN SECTION): ADENOCARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

[REDACTED] LUNG, LEFT UPPER LOBE, BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back [REDACTED]

Microscopic Description

Microscopic examination performed.

[REDACTED]

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Anat Path Reports

* Final Report *

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Source: NCI Genomic Data Commons file 2f71c5f6-f211-4df6-b581-13d0c43e8fb4 (TCGA-94-7557.9C906FE6-AF3F-42D4-AD03-4CFE825C92D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).